Somatic mutation profile of tumor specimen MP2PRT-PARDLC-TBP1-A (aliquot MP2PRT-PARDLC-TBP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARDLC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,052 days).
Specimen MP2PRT-PARDLC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cd8ec4b-75ab-42a2-8d1b-2348876a16ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARDLC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARDLC-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/789096a5-30fa-45a9-96e3-5462e627c431

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANXA13 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 85/231 reads (37%) | catalogued as rs1178174849, COSV51622160; called by muse, mutect2, varscan2
- FOXN1 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 272/703 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs551310590, COSV56883903; called by muse, mutect2, varscan2
- H4C12 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100694731, COSV100694760, COSV100694763; called by muse, mutect2, varscan2
- OR8G1 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.014); catalogued as rs767885287; called by muse, mutect2, varscan2
- PGK2 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV59162962; called by muse, mutect2, varscan2
- SLCO1A2 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs201943341; called by muse, mutect2, varscan2
- SPEG | c.9530G>A p.R3177H | Missense Mutation (SNP) | VAF 201/520 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs199580811; called by muse, mutect2, varscan2
- ZC2HC1A | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1290638849; called by muse, mutect2, varscan2
- FAM47B | c.736C>G p.H246D | Missense Mutation (SNP) | VAF 142/218 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FSIP2 | c.18895C>G p.Q6299E | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- HENMT1 | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 126/328 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- IGHV1-69 | c.346G>C p.A116P | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- IGKV3OR2-268 | c.348del p.P117Pfs*? | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel*, varscan2
- KIAA1586 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRAS | c.38_40dup p.G13dup | In Frame Ins (INS) | VAF 70/286 reads (24%) | called by mutect2, pindel, varscan2
- PBXIP1 | c.431G>C p.R144P | Missense Mutation (SNP) | VAF 118/360 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.587); called by muse, varscan2
- RGL4 | c.872A>C p.D291A | Missense Mutation (SNP) | VAF 113/352 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SETD2 | c.6594_6595insCCTGTGT p.S2199Pfs*8 | Frame Shift Ins (INS) | VAF 121/424 reads (29%) | called by mutect2, pindel, varscan2
- TFAP2B | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 87/179 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 165/455 reads (36%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TRPS1 | c.128C>T p.S43L (on ENST00000220888 / NM_001330599.2; = p.S56L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/314 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- H4C3 | c.303C>T p.F101= | Silent (SNP) | VAF 110/348 reads (32%) | catalogued as rs778556234, COSV100619461, COSV58090166; called by muse, mutect2, varscan2
- PCDHA7 | c.2160G>A p.A720= | Silent (SNP) | VAF 108/325 reads (33%) | catalogued as rs1209808083, COSV100970459; called by muse, mutect2, varscan2
- PTPN11 | c.1362G>A p.P454= | Silent (SNP) | VAF 143/396 reads (36%) | catalogued as rs771967829; called by muse, mutect2, varscan2
